TCGA case TCGA-86-A4JF — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e01e4fb3-236a-4d16-9073-555876b688e9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Romania; Age at index: 56 years; Vital status: Dead; Days to death: 737 days (2.0 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 56.1 years (20,491 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 31 days; Days to treatment end: 171 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 444 days (1.2 years); Days to treatment end: 536 days (1.5 years); Treatment outcome: Complete Response.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 57.3 years (20,927 days); Days to diagnosis: 436 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (7 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Day 436 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 436 days (1.2 years).
- Days to follow up: 536 days (1.5 years); Disease response: With Tumor.
- Days to follow up: 737 days (2.0 years); Disease response: With Tumor.
- Karnofsky performance status: 20; ECOG performance status: 4; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 70; ECOG performance status: 2; Timepoint: Post Adjuvant Therapy.
- Karnofsky performance status: 90; ECOG performance status: 1; Timepoint: Preoperative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking quit year: 2012.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-86-A4JF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 940 mg.
  Slide TCGA-86-A4JF-01A-02-TSB: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-86-A4JF-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-86-A4JF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-86-A4JF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: No; Treatment outcome first course: Complete Remission/Response.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: Post-Adjuvant Therapy.
- Follow-up form 1, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 737 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 737 days; disease-free interval: event (new tumor event after initially disease-free), 436 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 436 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-86-A4JF-01A-11D-A24O-01): tumor purity 0.25, ploidy 3.59, whole-genome doublings 1.
